FM case AD12740 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/2be53da0-7370-4cca-a0b7-d786c539fa19

Female, 67.5 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; primary biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
